Somatic mutation profile of tumor specimen TCGA-EE-A29H-06A (aliquot TCGA-EE-A29H-06A-12D-A197-08) from TCGA case TCGA-EE-A29H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.3 years (22,397 days).
Specimen TCGA-EE-A29H-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2985a44-bd27-4bc7-a98e-7fdeb77324ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29H-10A (Blood Derived Normal), aliquot TCGA-EE-A29H-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/612583d6-6736-4f8d-b67b-3d24fed5412a

The open-access MAF lists 373 somatic variants for this specimen: 241 protein-altering or splice-affecting, 119 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 224, Silent 119, Nonsense Mutation 8, RNA 5, Intron 3, Frame Shift Del 3, 3'UTR 3, Splice Region 3, 5'UTR 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/108 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SCN3A | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs774195502, CM140384, COSV51800839; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TGFBI | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs121909210, CM971473, CM991173, COSV59350526; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55946143; called by muse, mutect2, varscan2
- ABI1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV61015335; called by muse, varscan2
- ADAM12 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64103216; called by muse, mutect2, varscan2
- ADAM18 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as COSV55844392; called by muse, mutect2, varscan2
- ADAM22 | c.2144T>C p.F715S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55970984; called by muse, mutect2, varscan2
- ADGRB1 | c.1822del p.A608Pfs*37 | Frame Shift Del (DEL) | VAF 38/129 reads (29%) | catalogued as COSV60098853; called by mutect2, pindel*, varscan2
- ADGRG6 | c.2830A>G p.T944A | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs749400993, COSV51587532; called by muse, mutect2, varscan2
- ADGRV1 | c.9730G>A p.E3244K | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as COSV67979492; called by muse, mutect2, varscan2
- AGO2 | c.2405C>G p.P802R | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55045273, COSV55045514; called by muse, mutect2, varscan2
- AJM1 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.079); catalogued as rs753945927, COSV56031948; called by muse, mutect2, varscan2
- AKAP4 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62073830; called by muse, mutect2, varscan2
- AKR7A2 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs748386566, COSV52515750; called by muse, mutect2, varscan2
- AL121899.2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs267605853, COSV67349861; called by muse, mutect2, varscan2
- ANKAR | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55610055; called by muse, mutect2, varscan2
- AOC3 | c.2092G>A p.G698R | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57732767; called by muse, mutect2, varscan2
- AP3B1 | c.2809+1G>A p.X937_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV54877172; called by muse, mutect2
- ARHGEF2 | c.784C>T p.R262C (on ENST00000361247 / NM_001162383.2; = p.R234C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs144287482; called by muse, mutect2, varscan2
- ARNTL2 | c.1859A>G p.E620G | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1555169388, COSV53824004; called by muse, mutect2, varscan2
- ATP1A2 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV63402496; called by muse, mutect2, varscan2
- BAIAP3 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181343, COSV100181374; called by muse, mutect2, varscan2
- BAIAP3 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780935087, COSV100181345; called by muse, mutect2, varscan2
- BICD2 | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750918663, COSV63548091; called by muse, mutect2
- BIN2 | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs1202385654, COSV57203839; called by muse, mutect2, varscan2
- BRD1 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV53455115; called by muse, mutect2, varscan2
- BRD4 | c.3428C>T p.P1143L | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.291); catalogued as rs759208540, COSV99650349; called by muse, mutect2, varscan2
- BTBD11 | c.1052T>A p.L351Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV55018324; called by muse, mutect2, varscan2
- CACNA1H | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61985084; called by muse, mutect2, varscan2
- CACNA1S | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV62936832, COSV62939574; called by muse, mutect2, varscan2
- CACNA2D3 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 84/112 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs867317108, COSV55518389, COSV99878037; called by muse, mutect2, varscan2
- CADM2 | c.535C>T p.R179C (on ENST00000407528 / NM_001167674.2; = p.R181C on NM_153184.4) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs759648918, COSV101059551, COSV67359574; called by muse, mutect2, varscan2
- CADPS2 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs773480913, COSV57351573; called by muse, mutect2
- CAMSAP1 | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 16/28 reads (57%) | catalogued as COSV56719138; called by muse, mutect2, varscan2
- CCDC102B | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as rs200230135; called by muse, mutect2, varscan2
- CCDC130 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55582710; called by muse, mutect2, varscan2
- CCDC146 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV53544696; called by muse, mutect2, varscan2
- CCDC27 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53898726; called by muse, mutect2, varscan2
- CCDC40 | c.3308G>A p.R1103Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as rs762363791, COSV56407173; called by muse, mutect2, varscan2
- CCR8 | c.872C>T p.T291I | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0.14); catalogued as COSV58336818; called by muse, mutect2, varscan2
- CD163 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.177); catalogued as COSV63130017; called by muse, mutect2, varscan2
- CD276 | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100573337; called by muse, varscan2
- CD276 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573338; called by muse, mutect2, varscan2
- CD44 | c.1828C>T p.H610Y | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV53528338; called by muse, mutect2, varscan2
- CDH18 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776963132, COSV56899350; called by muse, mutect2, varscan2
- CELSR3 | c.6683G>A p.R2228Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.094); catalogued as rs1477034170, COSV50841186; called by muse, mutect2, varscan2
- CFAP54 | c.4735G>A p.E1579K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV61570915; called by muse, mutect2, varscan2
- CFAP70 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 64/98 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60281315; called by muse, mutect2, varscan2
- CGNL1 | c.3437G>A p.G1146E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV55564172; called by muse, mutect2, varscan2
- CIITA | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs778649467, COSV100162484, COSV60854529; called by muse, mutect2, varscan2
- CNTN5 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54285829; called by muse, mutect2, varscan2
- COL2A1 | c.2878G>A p.G960R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61528373; called by muse, varscan2
- COL5A1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.935); catalogued as rs776904091, COSV65665757; called by muse, mutect2, varscan2
- COL9A1 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV57879746; called by muse, mutect2, varscan2
- CPAMD8 | c.4171G>A p.G1391R (on ENST00000651564; = p.G1344R on NM_015692.5) | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV71595857; called by muse, mutect2, varscan2
- CSMD3 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV52114257; called by muse, mutect2, varscan2
- CSTF1 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV53858075; called by muse, mutect2, varscan2
- CXorf21 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV66762472, COSV66763043; called by muse, mutect2, varscan2
- CYP4X1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as rs752372409, COSV64149569; called by muse, mutect2, varscan2
- CYSLTR1 | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV64819496; called by muse, mutect2, varscan2
- DCC | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1421823846, COSV59087419; called by muse, mutect2, varscan2
- DENND4A | c.3953T>C p.V1318A | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV71265341; called by muse, mutect2, varscan2
- DGCR8 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.844); catalogued as COSV100707781, COSV61225832; called by muse, mutect2, varscan2
- DNAH2 | c.5546G>A p.G1849E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66717143; called by muse, mutect2, varscan2
- DNAH5 | c.13000G>A p.D4334N | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV54207549; called by muse, mutect2, varscan2
- DNAH5 | c.5105C>T p.S1702F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542591554, COSV54202517; called by muse, mutect2, varscan2
- DNAH5 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs560939419, COSV54203651, COSV99453001; called by muse, mutect2
- DST | c.3688C>T p.H1230Y (on ENST00000361203 / NM_001374722.1; = p.H904Y on NM_001723.6) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs868279643, COSV55000633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL3 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV57455034; called by muse, mutect2, varscan2
- EBF1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV58169176; called by muse, mutect2, varscan2
- EDNRB | c.356G>A p.R119K (on ENST00000377211 / NM_001201397.1; = p.R29K on NM_000115.5) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV57519396; called by muse, mutect2
- ELAVL2 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV56358129; called by muse, mutect2, varscan2
- ELMO2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1424847566, COSV99281593; called by muse, mutect2, varscan2
- EPPK1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs545014988, COSV101599789, COSV73260886; called by muse, mutect2, varscan2
- ERBB4 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV53506960; called by muse, mutect2, varscan2
- F2 | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV61314884; called by muse, mutect2, varscan2
- FAM118B | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV64156676; called by muse, mutect2, varscan2
- FASLG | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60679817; called by muse, mutect2, varscan2
- FAT3 | c.2702C>T p.S901F | Missense Mutation (SNP) | VAF 233/577 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.109); catalogued as COSV53081653; called by muse, mutect2, varscan2
- FBXW11 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.546); catalogued as COSV51605908; called by muse, mutect2, varscan2
- FGL2 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1373659990, COSV50380405; called by muse, mutect2, varscan2
- FLG | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs112248790, COSV64237637; called by muse, mutect2, varscan2
- FOXK1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100194958; called by muse, mutect2, varscan2
- FOXK1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61066119, COSV61067325; called by muse, mutect2
- FOXS1 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV54065100; called by muse, mutect2, varscan2
- GAB4 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as COSV101271954; called by muse, varscan2
- GAB4 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV101271955; called by muse, varscan2
- GABRA6 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV50877917; called by muse, mutect2, varscan2
- GALNT6 | c.1503C>T p.I501= | Splice Region (SNP) | VAF 27/52 reads (52%) | catalogued as COSV62541751; called by muse, mutect2, varscan2
- GALNTL6 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs146923140; called by muse, mutect2, varscan2
- GLDN | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1439008637, COSV59089026; called by muse, mutect2, varscan2
- GPER1 | c.996G>C p.R332S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV52468013; called by muse, mutect2, varscan2
- GZMA | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV57112084; called by muse, mutect2, varscan2
- HES1 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV51683856; called by muse, mutect2, varscan2
- HOXD10 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV50898357; called by muse, mutect2, varscan2
- HOXD13 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.186); catalogued as COSV66832352; called by muse, mutect2, varscan2
- HRG | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV104372070, COSV51644246; called by muse, mutect2, varscan2
- HSPA4L | c.2182C>T p.H728Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV56544001; called by muse, mutect2, varscan2
- IGHV6-1 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1566952528; called by muse, mutect2, varscan2
- IL2RB | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868058366, COSV53425110; called by muse, mutect2, varscan2
- IL33 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs778800068, COSV67342781; called by muse, mutect2, varscan2
- INPP5J | c.2083C>T p.P695S (on ENST00000331075 / NM_001284285.2; = p.P327S on NM_001002837.2) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs745466849, COSV58511784; called by muse, mutect2, varscan2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, mutect2, varscan2
- ITGA7 | c.2383G>A p.G795R (on ENST00000555728; = p.G751R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565621669, COSV57692470; called by muse, mutect2, varscan2
- JAML | c.274G>A p.G92R (on ENST00000356289 / NM_001098526.2; = p.G82R on NM_153206.3) | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99409418; called by muse, mutect2, varscan2
- JAML | c.273G>A p.M91I (on ENST00000356289 / NM_001098526.2; = p.M81I on NM_153206.3) | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99409423; called by muse, varscan2
- KDM4B | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50285137; called by muse, mutect2, varscan2
- KHDC3L | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as rs1242601835, COSV64868914; called by muse, mutect2, varscan2
- KLHDC7A | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs1431037748, COSV68769110; called by muse, mutect2, varscan2
- KLHL4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as COSV64139565; called by muse, mutect2, varscan2
- LRIG1 | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56237447; called by muse, mutect2, varscan2
- LRP2BP | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60749352; called by muse, mutect2, varscan2
- LRRC3B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as rs1447656470, COSV67519995; called by muse, varscan2
- LRRC7 | c.3026G>A p.G1009E (on ENST00000651989 / NM_001370785.2; = p.G976E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); catalogued as COSV50416330; called by muse, mutect2, varscan2
- LRRCC1 | c.1767G>A p.R589= | Splice Region (SNP) | VAF 17/27 reads (63%) | catalogued as COSV64482723; called by muse, mutect2, varscan2
- MAP3K9 | c.2998A>T p.N1000Y (on ENST00000554752 / NM_001284230.1; = p.N1014Y on NM_033141.4) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.122); catalogued as COSV67120130; called by muse, mutect2, varscan2
- MCHR2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56000050, COSV56003328; called by muse, mutect2, varscan2
- MED12L | c.6217C>T p.P2073S | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as rs1279239457, COSV99850937; called by muse, mutect2, varscan2
- MED12L | c.6218C>T p.P2073L | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV56372813, COSV99852555; called by muse, mutect2, varscan2
- MGAM | c.625G>C p.A209P | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV71885039, COSV71886131; called by muse, mutect2, varscan2
- MGAM | c.3591C>G p.F1197L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV72073828; called by muse, varscan2
- MGAM | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72073829; called by muse, varscan2
- MIPOL1 | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs1436133259, COSV59380191; called by muse, mutect2, varscan2
- MON1B | c.1573C>A p.P525T | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV50245511; called by muse, mutect2, varscan2
- MOSPD2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV66859700; called by muse, mutect2, varscan2
- MROH2B | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs896065939, COSV101270609, COSV68181699; called by muse, mutect2, varscan2
- MSX2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs367897914; called by muse, mutect2, varscan2
- MTG2 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63693408; called by muse, mutect2, varscan2
- MTUS2 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as COSV70914179; called by muse, mutect2, varscan2
- MUC16 | c.9307G>A p.E3103K | Missense Mutation (SNP) | VAF 122/162 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67448740; called by muse, mutect2, varscan2
- MXRA5 | c.7520G>A p.S2507N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV54225614; called by muse, mutect2
- MXRA5 | c.4918C>T p.R1640C | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs751486197, COSV54225635, COSV54239674; called by muse, mutect2, varscan2
- MYH1 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV56844397; called by muse, mutect2, varscan2
- NAALADL1 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV60523027; called by muse, mutect2, varscan2
- NAALADL2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs199919300, COSV70794470; called by muse, mutect2, varscan2
- NAT2 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV54061330, COSV54062296; called by muse, mutect2, varscan2
- NFASC | c.433G>A p.E145K (on ENST00000339876 / NM_001378329.1; = p.E139K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1232973455, COSV58377995; called by muse, mutect2, varscan2
- NOBOX | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1278448515, COSV56192887; called by muse, mutect2, varscan2
- NOP2 | c.1783C>A p.Q595K (on ENST00000322166 / NM_001258308.2; = p.Q591K on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV59109666; called by muse, mutect2, varscan2
- NPY5R | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58451202; called by muse, mutect2, varscan2
- NR3C2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as COSV60986014; called by muse, mutect2, varscan2
- NSL1 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV65328026; called by muse, mutect2, varscan2
- NTRK3 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs780933441, COSV62297014; called by muse, mutect2, varscan2
- NUP210 | c.2722C>T p.P908S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99596006; called by muse, mutect2, varscan2
- ODF3L2 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV52744121; called by muse, mutect2, varscan2
- OR10G8 | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.49); PolyPhen benign (0.122); catalogued as COSV70908213, COSV70908425; called by muse, mutect2, varscan2
- OR1L3 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs766370067, COSV59169264; called by muse, mutect2, varscan2
- OR2M2 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.049); catalogued as rs1019556879, COSV100677356, COSV62897910; called by muse, mutect2, varscan2
- OR2T12 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58775820; called by muse, mutect2, varscan2
- OR2T33 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58814348; called by muse, mutect2, varscan2
- OR4D9 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs544480577, COSV61434157; called by muse, mutect2, varscan2
- OR51S1 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59057378, COSV59059768; called by muse, mutect2, varscan2
- OR52B4 | c.596G>T p.W199L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV68768623; called by muse, mutect2, varscan2
- OR52N1 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1403316614, COSV57692994; called by muse, mutect2, varscan2
- OR5J2 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV104394845, COSV56620275, COSV56622482; called by muse, mutect2, varscan2
- OTOP3 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.366); catalogued as rs1384792762, COSV60912462; called by muse, mutect2, varscan2
- PARP10 | c.2122C>T p.Q708* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV57296896; called by mutect2, varscan2
- PAX6 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53792116; called by muse, mutect2, varscan2
- PCDHA3 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100793171, COSV63539275; called by muse, mutect2, varscan2
- PDE4D | c.1817C>T p.S606F (on ENST00000340635 / NM_001104631.2; = p.S470F on NM_006203.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV57715431; called by muse, mutect2, varscan2
- PECR | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as rs1207196049, COSV99526721; called by muse, mutect2, varscan2
- PLB1 | c.3154C>T p.R1052W | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs150999428, CM141403; called by muse, mutect2, varscan2
- PRLR | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.515); catalogued as rs200582882, COSV51493388, COSV51500924; called by muse, mutect2, varscan2
- PROKR2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773364376, COSV54085515; called by muse, mutect2, varscan2
- PTH2R | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as rs144936061; called by muse, mutect2, varscan2
- PTPRT | c.2315G>A p.R772K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.267); catalogued as COSV61963685, COSV62031808; called by muse, mutect2, varscan2
- PWWP3B | c.1394G>T p.S465I | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61798506; called by muse, mutect2, varscan2
- PXDNL | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1382975864, COSV62477614; called by muse, mutect2, varscan2
- PZP | c.4415C>T p.P1472L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99737358; called by muse, mutect2, varscan2
- PZP | c.4414C>T p.P1472S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549632827, COSV99737363; called by muse, mutect2, varscan2
- RBM10 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61308085; called by muse, mutect2, varscan2
- RBM11 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 109/172 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs774910187, COSV68747976; called by muse, varscan2
- RGS7 | c.1356A>T p.K452N | Missense Mutation (SNP) | VAF 69/132 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV58532213; called by muse, mutect2, varscan2
- RIPOR3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50385924; called by muse, mutect2, varscan2
- RP1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV55110720; called by muse, mutect2, varscan2
- RP1 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs866399055, COSV55111239; called by muse, mutect2, varscan2
- RUFY4 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs773995516, COSV60246305; called by muse, mutect2, varscan2
- S100A2 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64184592; called by muse, mutect2, varscan2
- SCN10A | c.3715G>A p.E1239K | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101479289, COSV71860462; called by muse, mutect2, varscan2
- SERPINA10 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56227581; called by muse, mutect2, varscan2
- SETBP1 | c.4373G>A p.R1458K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56314381; called by muse, mutect2
- SLC36A1 | c.1348G>C p.V450L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV54652331; called by muse, mutect2, varscan2
- SLC4A10 | c.3259G>A p.E1087K (on ENST00000446997 / NM_001354461.2; = p.E1057K on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV55766507; called by muse, mutect2, varscan2
- SLC9C2 | c.2552C>A p.P851Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV62944208; called by muse, mutect2, varscan2
- SLCO1B3 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs369045586, COSV53933377; called by muse, mutect2, varscan2
- SNAP25 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.489); catalogued as COSV54770803; called by muse, mutect2, varscan2
- SNTA1 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV54128428; called by muse, mutect2, varscan2
- SNTB1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as rs144965371; called by muse, mutect2, varscan2
- SPAG9 | c.2765C>T p.P922L (on ENST00000262013 / NM_001130528.3; = p.P908L on NM_003971.6) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV56231924; called by muse, mutect2
- SSC4D | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51881491; called by muse, mutect2, varscan2
- STAB2 | c.1622G>A p.G541E | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as rs1019825353, COSV66335198, COSV66344098; called by muse, mutect2, varscan2
- STK26 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61228980; called by muse, mutect2, varscan2
- STXBP5L | c.3316G>A p.G1106R | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV56502247; called by muse, mutect2, varscan2
- SVEP1 | c.4340C>T p.S1447F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV57030472; called by muse, mutect2, varscan2
- TACR3 | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV59198676, COSV59202465; called by muse, mutect2, varscan2
- TCERG1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as COSV57034210; called by muse, mutect2, varscan2
- TEKT5 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51586953; called by muse, varscan2
- THEMIS | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV64069513; called by muse, mutect2, varscan2
- TLL1 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.119); catalogued as rs150952504; called by muse, mutect2, varscan2
- TMEM218 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54444838; called by muse, mutect2, varscan2
- TMEM223 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53667384; called by muse, mutect2
- TMPRSS11A | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58356771; called by muse, mutect2, varscan2
- TNC | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs754322466, COSV60781136; called by muse, mutect2, varscan2
- TNNI3K | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs747300364, COSV58547042; called by muse, mutect2, varscan2
- TNR | c.3958-1G>T p.X1320_splice | Splice Site (SNP) | VAF 36/77 reads (47%) | catalogued as COSV99688970; called by muse, mutect2, varscan2
- TNXB | c.8006C>T p.S2669F (on ENST00000647633; = p.S2422F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/436 reads (34%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.942); catalogued as COSV64474561; called by muse, mutect2
- TOM1L1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.662); catalogued as COSV61946716; called by muse, mutect2, varscan2
- TP53BP1 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 41/101 reads (41%) | catalogued as rs1298603817, COSV55497004; called by muse, mutect2, varscan2
- TP63 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV53198253, COSV53205358; called by muse, mutect2, varscan2
- TRBV4-1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as rs765414781; called by muse, mutect2, varscan2
- TRHDE | c.1224C>G p.N408K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53834982; called by muse, mutect2, varscan2
- TSPAN16 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.77); PolyPhen benign (0.073); catalogued as COSV57441561; called by muse, mutect2, varscan2
- TTN | c.28654G>A p.E9552K (on ENST00000591111; = p.E8625K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/129 reads (41%) | PolyPhen probably damaging (0.994); catalogued as COSV59895218; called by muse, mutect2, varscan2
- TTN | c.15805G>A p.E5269K (on ENST00000591111; = p.E4342K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/173 reads (34%) | PolyPhen benign (0.053); catalogued as COSV59911701; called by muse, mutect2, varscan2
- TXNDC2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.063); catalogued as COSV60152301; called by muse, mutect2, varscan2
- U2SURP | c.1936T>G p.F646V | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV67530185; called by muse, mutect2, varscan2
- UBAC2 | c.159G>A p.Q53= (on ENST00000403766 / NM_001144072.2; = p.S95N on NM_177967.4) | Splice Region (SNP) | VAF 97/270 reads (36%) | catalogued as COSV63117165; called by muse, mutect2, varscan2
- UBE2J1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV70560945; called by muse, mutect2, varscan2
- UGT2B28 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV59430877, COSV59434501; called by muse, mutect2, varscan2
- UGT3A2 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56928859; called by muse, mutect2, varscan2
- USP31 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54849802; called by muse, mutect2, varscan2
- USP42 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100084280; called by muse, mutect2, varscan2
- VEGFD | c.805T>A p.C269S | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52909075; called by muse, mutect2, varscan2
- VEZT | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54136647; called by muse, mutect2, varscan2
- VPS33A | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252666084, COSV57356228; called by muse, mutect2, varscan2
- XIRP2 | c.9311C>T p.S3104F (on ENST00000628543; = p.S3279F on NM_152381.6) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.296); catalogued as COSV54685526; called by muse, mutect2, varscan2
- XPNPEP2 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as COSV64367788; called by muse, mutect2, varscan2
- XPO4 | c.1945T>C p.Y649H | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55004464; called by muse, mutect2, varscan2
- ZNF136 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59710149; called by muse, mutect2, varscan2
- ZNF208 | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV68101556, COSV68108787; called by muse, varscan2
- ZNF229 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.48); PolyPhen benign (0.382); catalogued as COSV52160095, COSV52162794; called by muse, mutect2, varscan2
- ZNF407 | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs750218080, COSV55244527; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF519 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV73913186; called by muse, mutect2, varscan2
- CNOT1 | c.2490dup p.Q831Sfs*11 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- CYTH2 | c.838del p.R280Afs*30 (on ENST00000427476; = p.R279Afs*30 on NM_004228.7) | Frame Shift Del (DEL) | VAF 34/56 reads (61%) | called by mutect2, pindel, varscan2
- GPR179 | c.5219G>A p.G1740E (on ENST00000621958; = p.G1739E on NM_001004334.4) | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- IGLJ5 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 31/81 reads (38%) | PolyPhen probably damaging (0.98); called by muse, mutect2
- PRAMEF7 | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.373); called by mutect2, varscan2
- TRAV17 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USF3 | c.2788_2798del p.A930Cfs*17 | Frame Shift Del (DEL) | VAF 28/52 reads (54%) | called by mutect2, pindel, varscan2
- ADH6 | c.499C>T p.L167= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as COSV52955190; called by muse, varscan2
- ANKS6 | c.426G>A p.R142= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs756644622, COSV62049170; called by muse, mutect2, varscan2
- ANO2 | c.2280C>T p.P760= (on ENST00000356134 / NM_001278597.3; = p.P764= on NM_001278596.3) | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV59009758, COSV59014140; called by muse, mutect2, varscan2
- ANO2 | c.1575G>A p.K525= (on ENST00000356134 / NM_001278597.3; = p.K529= on NM_001278596.3) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV59009788; called by muse, mutect2, varscan2
- AOC1 | c.84G>A p.R28= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV62867192; called by muse, mutect2, varscan2
- ASCC3 | c.1911C>T p.S637= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV61226146; called by muse, mutect2, varscan2
- ASH1L | c.8284T>C p.L2762= (on ENST00000368346 / NM_001366177.2; = p.L2757= on NM_018489.3) | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV64205920; called by muse, mutect2, varscan2
- ATF6B | c.2007G>A p.Q669= | Silent (SNP) | VAF 221/549 reads (40%) | catalogued as rs768672363, COSV64351385; called by muse, mutect2, varscan2
- BRD4 | c.3429C>T p.P1143= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as rs201578775, COSV99650345; called by muse, mutect2, varscan2
- C1QTNF2 | c.684C>T p.S228= (on ENST00000393975; = p.S183= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV67432425; called by muse, mutect2, varscan2
- C1QTNF3 | c.720C>T p.F240= | Silent (SNP) | VAF 71/161 reads (44%) | catalogued as COSV51467777; called by muse, mutect2, varscan2
- C4BPA | c.1137G>A p.R379= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV65535807; called by muse, mutect2, varscan2
- CCDC80 | c.498C>T p.L166= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV52815249; called by muse, mutect2, varscan2
- CCDC88C | c.1827G>A p.L609= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs754907863, COSV66234660; called by muse, mutect2, varscan2
- CCNT2 | c.1795C>T p.L599= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV51471276; called by muse, mutect2, varscan2
- CDH6 | c.2094C>T p.F698= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV54065182; called by muse, mutect2, varscan2
- CEACAM18 | c.102C>T p.I34= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV67282295; called by muse, mutect2, varscan2
- CFHR4 | c.1341C>T p.F447= (on ENST00000367416 / NM_001201551.2; = p.F201= on NM_006684.5) | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV52225228; called by muse, mutect2
- CHRM2 | c.834G>A p.E278= | Silent (SNP) | VAF 53/77 reads (69%) | catalogued as COSV57766502, COSV57782901; called by muse, mutect2, varscan2
- CLCN7 | c.1182C>T p.A394= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs367549656; called by muse, mutect2, varscan2
- CLDN17 | c.396C>T p.F132= | Silent (SNP) | VAF 39/54 reads (72%) | catalogued as rs765477205, COSV54522355; called by muse, mutect2, varscan2
- CRYGN | c.306T>C p.G102= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1251008630, COSV61563609; called by muse, mutect2, varscan2
- CYP11A1 | c.246C>T p.F82= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV51430842, COSV51431089; called by muse, mutect2, varscan2
- DCLK3 | c.1548C>T p.T516= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs750226765, COSV69362382; called by muse, mutect2, varscan2
- DMXL2 | c.7575C>T p.F2525= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as COSV51841546; called by muse, mutect2, varscan2
- E2F1 | c.303G>T p.L101= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV58534553; called by muse, mutect2, varscan2
- ELAVL2 | c.684A>G p.G228= | Silent (SNP) | VAF 81/129 reads (63%) | catalogued as COSV56358117; called by muse, mutect2, varscan2
- EPB41L3 | c.1551C>T p.S517= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV59446007; called by muse, mutect2, varscan2
- EYS | c.1503C>T p.F501= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV60977902, COSV60993411; called by muse, mutect2, varscan2
- FAH | c.519C>T p.I173= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV55720328; called by muse, mutect2, varscan2
- FUS | c.210A>T p.S70= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as COSV54215730; called by muse, mutect2, varscan2
- GAD1 | c.504C>T p.I168= | Silent (SNP) | VAF 54/109 reads (50%) | catalogued as COSV60151680; called by muse, mutect2, varscan2
- GCFC2 | c.735T>A p.L245= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV58079804; called by muse, mutect2, varscan2
- GFRA3 | c.705C>T p.I235= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs761719695, COSV51227998, COSV51230016; called by muse, mutect2, varscan2
- GIMAP5 | c.117G>A p.G39= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1478002016, COSV57529681; called by muse, mutect2, varscan2
- GLYATL2 | c.663T>C p.C221= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV54849180; called by muse, mutect2, varscan2
- GPR3 | c.738T>C p.I246= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV64994520; called by muse, mutect2, varscan2
- GPR32 | c.147C>T p.I49= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as rs1347519981, COSV54513834; called by muse, mutect2, varscan2
- GRIA2 | c.1359C>T p.I453= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs752578545, COSV52383835; called by muse, mutect2, varscan2
- GRIN2A | c.2691C>T p.L897= | Silent (SNP) | VAF 59/165 reads (36%) | catalogued as COSV58022685; called by muse, mutect2, varscan2
- GRK2 | c.936C>T p.F312= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs1247441425, COSV57950577; called by muse, mutect2, varscan2
- HIVEP1 | c.3555C>T p.H1185= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1302163134, COSV65099189; called by muse, mutect2, varscan2
- HS3ST2 | c.792C>T p.F264= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV54458855; called by muse, varscan2
- IDE | c.102C>T p.F34= | Silent (SNP) | VAF 170/234 reads (73%) | catalogued as rs945519873, COSV56421853; called by muse, mutect2, varscan2
- IGKV1-17 | c.180G>A p.Q60= | Silent (SNP) | VAF 74/170 reads (44%) | catalogued as rs772396884; called by muse, mutect2, varscan2
- IQCA1 | c.1740G>A p.G580= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV54497132; called by muse, mutect2, varscan2
- ITPRID2 | c.447G>A p.Q149= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV57469948; called by muse, varscan2
- KDM4B | c.981C>T p.P327= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs147526641, COSV99346561; called by muse, mutect2, varscan2
- KIAA1109 | c.14742T>C p.Y4914= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs750929994, COSV52664115; called by muse, mutect2, varscan2
- KIF4B | c.3504C>T p.I1168= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV70528112; called by muse, mutect2, varscan2
- KIR2DL3 | c.513C>T p.F171= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as rs201689798; called by muse, mutect2, varscan2
- KRT72 | c.1503G>A p.G501= | Silent (SNP) | VAF 78/185 reads (42%) | catalogued as rs959831702, COSV53373372; called by muse, mutect2, varscan2
- LMO7 | c.4029A>G p.Q1343= (on ENST00000357063; = p.Q1024= on NM_005358.5) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV58531062; called by muse, mutect2, varscan2
- LPIN1 | c.1977C>T p.C659= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV56762959; called by muse, mutect2, varscan2
- LRRC3B | c.240C>T p.P80= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs149543241, COSV67520245; called by muse, varscan2
- LYSMD4 | c.522C>T p.D174= (on ENST00000409796 / NM_001284417.2; = p.D175= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV60386020; called by muse, mutect2, varscan2
- MAGEB6 | c.699C>T p.F233= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs867212343, COSV66871960; called by muse, mutect2, varscan2
- MAGI2 | c.2793C>T p.F931= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs587780387, COSV62637454; ClinVar: likely benign; called by muse, mutect2, varscan2
- MDGA1 | c.2550C>T p.L850= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV51792444; called by muse, mutect2
- MGAM | c.3366C>T p.I1122= | Silent (SNP) | VAF 90/242 reads (37%) | catalogued as rs534249205, COSV72073823; called by muse, varscan2
- MGAM | c.3393C>T p.L1131= | Silent (SNP) | VAF 87/228 reads (38%) | catalogued as COSV72073825; called by muse, varscan2
- MTHFR | c.792C>T p.S264= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1309422719, COSV64876956; called by muse, mutect2, varscan2
- NKAP | c.708G>A p.K236= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV65055969; called by muse, mutect2, varscan2
- NTNG2 | c.987G>A p.R329= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs765317291, COSV62364890; called by muse, mutect2
- NUMA1 | c.450C>T p.F150= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV61183633; called by muse, mutect2, varscan2
- NUP210 | c.3276C>T p.I1092= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs752404764, COSV54403141; called by muse, mutect2
- NUP210 | c.2721C>T p.H907= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV99596007; called by muse, mutect2, varscan2
- OR1Q1 | c.522C>T p.I174= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV52917403; called by muse, mutect2, varscan2
- OR2AG2 | c.819C>T p.I273= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs755240084, COSV58454689, COSV58455838; called by muse, mutect2, varscan2
- OR2T12 | c.962G>A p.*321= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as rs866792488, COSV58776610; called by muse, mutect2, varscan2
- OR2T2 | c.960G>A p.V320= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs1323021711, COSV61617731; called by mutect2, varscan2
- OR52A5 | c.753C>T p.F251= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV56614386; called by muse, mutect2, varscan2
- OR52M1 | c.453C>T p.L151= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs758254331, COSV64171544; called by muse, mutect2, varscan2
- OR5M10 | c.588G>A p.K196= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs745952056, COSV73242260, COSV73242270; called by muse, mutect2, varscan2
- OR5R1 | c.18C>T p.I6= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV56571587; called by muse, mutect2, varscan2
- OR5V1 | c.879G>A p.R293= | Silent (SNP) | VAF 54/103 reads (52%) | catalogued as COSV65826612; called by muse, mutect2, varscan2
- OR8U1 | c.912C>T p.I304= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV56414370; called by muse, mutect2, varscan2
- PCDHB12 | c.567G>A p.R189= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV53393706; called by muse, mutect2, varscan2
- PCDHB2 | c.426G>A p.L142= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs1554271191, COSV52029848; called by muse, mutect2, varscan2
- PCDHGB1 | c.1344C>T p.F448= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV53907546, COSV53930784; called by muse, mutect2, varscan2
- PECR | c.618C>T p.S206= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as COSV54733605, COSV54735600; called by muse, mutect2, varscan2
- PFKFB1 | c.837C>T p.R279= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs749925058, COSV66627840; called by muse, mutect2
- PHACTR3 | c.1566G>A p.T522= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as rs370671908; called by muse, mutect2, varscan2
- PLEKHA7 | c.1224G>A p.G408= | Silent (SNP) | VAF 50/125 reads (40%) | catalogued as rs779873733, COSV100850370, COSV63044107; called by muse, mutect2, varscan2
- PRDM16 | c.1029G>A p.V343= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV54580539; called by muse, mutect2, varscan2
- PRSS1 | c.423C>T p.I141= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as COSV61190944; called by muse, mutect2, varscan2
- PTGES2 | c.310C>T p.L104= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV52968152; called by muse, mutect2, varscan2
- RAP1GAP2 | c.928C>T p.L310= | Silent (SNP) | VAF 89/130 reads (68%) | catalogued as COSV54572490; called by muse, mutect2, varscan2
- REG4 | c.189C>T p.N63= | Silent (SNP) | VAF 162/438 reads (37%) | catalogued as rs756035160, COSV56652208, COSV56654550; called by muse, mutect2, varscan2
- RELN | c.7911C>T p.R2637= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV58988091; called by muse, mutect2
- RHOBTB1 | c.1893C>T p.F631= | Silent (SNP) | VAF 53/77 reads (69%) | catalogued as COSV61957862; called by muse, mutect2, varscan2
- RIMBP2 | c.2922C>T p.V974= | Silent (SNP) | VAF 121/288 reads (42%) | catalogued as rs866605506, COSV55464017; called by muse, mutect2, varscan2
- RO60 | c.787T>C p.L263= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV66473264; called by muse, mutect2
- RSPO2 | c.582G>A p.R194= | Silent (SNP) | VAF 134/215 reads (62%) | catalogued as COSV52639299; called by muse, mutect2, varscan2
- RYR3 | c.12006A>G p.E4002= (on ENST00000389232; = p.E4003= on NM_001036.6) | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as COSV66779869; called by muse, mutect2, varscan2
- SCN10A | c.4026C>T p.F1342= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV71860461; called by muse, mutect2, varscan2
- SHROOM2 | c.3969C>T p.I1323= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs1308167839, COSV66604993; called by muse, mutect2, varscan2
- SLC17A6 | c.927C>T p.S309= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV54133950; called by muse, mutect2, varscan2
- SLC8A3 | c.1068C>T p.I356= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV63519352; called by muse, mutect2, varscan2
- SLC9A2 | c.249G>A p.E83= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV52129323; called by muse, mutect2, varscan2
- SLIT2 | c.4110G>A p.R1370= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV56562215; called by muse, mutect2, varscan2
- SMYD3 | c.603C>T p.I201= (on ENST00000490107 / NM_001375962.1; = p.I142= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs74523188, COSV63625822; called by muse, mutect2, varscan2
- SPTBN1 | c.6126C>T p.S2042= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV61686036; called by muse, mutect2, varscan2
- STC2 | c.216G>A p.E72= | Silent (SNP) | VAF 111/272 reads (41%) | catalogued as COSV54178535; called by muse, mutect2, varscan2
- TANC2 | c.4746C>T p.S1582= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV67330873; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2562C>T p.S854= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV51510188; called by muse, mutect2, varscan2
- TKFC | c.138G>A p.K46= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV57101293; called by muse, mutect2, varscan2
- TMEM200A | c.108G>A p.E36= | Silent (SNP) | VAF 59/85 reads (69%) | catalogued as COSV51649867; called by muse, mutect2, varscan2
- TPTE2 | c.951G>A p.A317= (on ENST00000400230 / NM_199254.2; = p.A240= on NM_130785.3) | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs574289737, COSV55016906; called by muse, mutect2, varscan2
- TTYH1 | c.1143G>A p.L381= | Silent (SNP) | VAF 25/34 reads (74%) | catalogued as COSV56609913; called by muse, mutect2, varscan2
- UGT2B28 | c.28C>T p.L10= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as COSV59430867, COSV59432001; called by muse, mutect2, varscan2
- USP28 | c.2814G>A p.R938= | Silent (SNP) | VAF 60/81 reads (74%) | catalogued as COSV50156310; called by muse, mutect2, varscan2
- USP42 | c.1305C>T p.P435= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as rs780149997, COSV60361076; called by muse, varscan2
- VN1R2 | c.906T>C p.N302= | Silent (SNP) | VAF 57/87 reads (66%) | catalogued as rs113115189, COSV59037302; called by muse, mutect2, varscan2
- YY2 | c.537G>T p.L179= | Silent (SNP) | VAF 70/184 reads (38%) | catalogued as COSV63410852; called by muse, mutect2, varscan2
- ZBTB7C | c.1656G>A p.E552= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs1170358368, COSV59687813; called by muse, mutect2
- ZKSCAN5 | c.1680G>A p.Q560= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV58742001; called by muse, mutect2, varscan2
- ZNF705A | c.708C>T p.A236= | Silent (SNP) | VAF 69/196 reads (35%) | catalogued as COSV63732879; called by muse, mutect2, varscan2
- ZNF718 | c.891C>T p.S297= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV68140301; called by muse, mutect2, varscan2
- ATP2B4 | c.3309+2056C>T | Intron (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100397258, COSV100397405; called by mutect2, varscan2
- ATP6AP1L | n.1971A>G | RNA (SNP) | VAF 26/83 reads (31%) | catalogued as COSV66474473; called by muse, mutect2, varscan2
- FAM183BP | n.1021G>A | RNA (SNP) | VAF 29/89 reads (33%) | catalogued as rs1345186615; called by muse, mutect2, varscan2
- FCRL4 | c.-1C>T | 5'UTR (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99619571; called by muse, mutect2, varscan2
- FGFR3 | c.*782G>A | 3'UTR (SNP) | VAF 32/48 reads (67%) | catalogued as COSV53393534; called by muse, mutect2, varscan2
- IQCF2 | c.-1C>T | 5'UTR (SNP) | VAF 14/172 reads (8%) | catalogued as rs1395870810, COSV100291024; called by muse, mutect2
- MIR1261 | n.13G>A | RNA (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- MIR526B | n.80C>T | RNA (SNP) | VAF 20/25 reads (80%) | called by muse, mutect2, varscan2
- SSPOP | n.6622C>T | RNA (SNP) | VAF 82/120 reads (68%) | catalogued as rs1010841371, COSV50486613; called by muse, mutect2
- TRIM8 | c.*692C>T | 3'UTR (SNP) | VAF 21/28 reads (75%) | called by muse, mutect2, varscan2
- TRIM8 | c.*693C>T | 3'UTR (SNP) | VAF 20/27 reads (74%) | catalogued as rs1187198843; called by muse, mutect2, varscan2
- TTN | c.10361-5001G>A | Intron (SNP) | VAF 36/106 reads (34%) | catalogued as COSV59976354; called by muse, mutect2, varscan2
- ZRANB2 | c.771-726C>T | Intron (SNP) | VAF 6/9 reads (67%) | catalogued as COSV99639237; called by muse, mutect2, varscan2
